Somatic mutation profile of tumor specimen MP2PRT-PAUGBS-TMP1-A (aliquot MP2PRT-PAUGBS-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUGBS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,529 days).
Specimen MP2PRT-PAUGBS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 302ceff0-f58a-4085-9c1c-a0bef19c8ba8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGBS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGBS-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f252cc6-8d08-488f-ad23-561c9faa18c6

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 55/482 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV101212170; called by muse, mutect2, varscan2
- GPX6 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 166/452 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs374833384, COSV62659046; called by muse, mutect2, varscan2
- KRT27 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 153/328 reads (47%) | catalogued as rs749978861; called by muse, mutect2, varscan2
- PAK5 | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 130/387 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62023037; called by muse, mutect2, varscan2
- TMEM179 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 226/646 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs574901720; called by muse, varscan2
- C2CD3 | c.1718C>A p.T573K | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- GIPC3 | c.1878C>A p.S626R | Missense Mutation (SNP) | VAF 168/468 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NRCAM | c.1226G>T p.S409I (on ENST00000379028 / NM_001371124.1; = p.S403I on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/159 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- PLPP3 | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA9 | c.219C>T p.D73= | Silent (SNP) | VAF 398/852 reads (47%) | catalogued as rs422432; called by muse, mutect2
- COL14A1 | c.5312-793C>T | Intron (SNP) | VAF 72/268 reads (27%) | called by muse, mutect2, varscan2
- KLHL9 | c.-452C>T | 5'UTR (SNP) | VAF 151/316 reads (48%) | called by muse, mutect2, varscan2
